Somatic mutation profile of tumor specimen TCGA-78-7166-01A (aliquot TCGA-78-7166-01A-12D-2063-08) from TCGA case TCGA-78-7166, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 84.5 years (30,869 days).
Specimen TCGA-78-7166-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b20afb2e-7923-48fb-87c3-7ddaa8ed98c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7166-11A (Solid Tissue Normal), aliquot TCGA-78-7166-11A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3783fb1-d04b-4132-bafc-ba27741c82e4

The open-access MAF lists 249 somatic variants for this specimen: 178 protein-altering or splice-affecting, 65 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 65, Nonsense Mutation 12, Frame Shift Del 7, Splice Site 5, Intron 4, Frame Shift Ins 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 11/19 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRB3 | c.3676G>T p.E1226* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV53247638; called by muse, mutect2, varscan2
- ADGRL3 | c.1321G>T p.D441Y (on ENST00000506720 / NM_001322402.2; = p.D373Y on NM_015236.6) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72268925, COSV72269605; called by muse, mutect2, varscan2
- ADIPOR2 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV63946576; called by muse, mutect2, varscan2
- ADRB3 | c.356T>A p.L119Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61462119; called by muse, mutect2, varscan2
- AHNAK | c.16813G>T p.A5605S | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.839); catalogued as COSV57216222; called by muse, mutect2, varscan2
- ANAPC1 | c.5086G>T p.V1696F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.303); catalogued as rs755821664, COSV100594925; called by muse, mutect2, varscan2
- ANK1 | c.2615T>A p.I872N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55883758; called by muse, mutect2, varscan2
- ARSF | c.1072C>A p.Q358K | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV63839860; called by muse, mutect2, varscan2
- ASB12 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209487235, COSV62857094; called by muse, mutect2
- AXL | c.2417C>A p.T806K (on ENST00000301178 / NM_021913.5; = p.T797K on NM_001699.6) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV56569419, COSV56577384; called by muse, mutect2, varscan2
- BACH1 | c.955G>T p.G319* | Nonsense Mutation (SNP) | VAF 54/187 reads (29%) | catalogued as COSV54519384; called by muse, mutect2, varscan2
- BAZ2B | c.5842C>T p.L1948F | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58602489, COSV58609279; called by muse, mutect2, varscan2
- BCL9L | c.1141G>T p.G381W | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52685179; called by muse, mutect2, varscan2
- BRD2 | c.535T>G p.S179A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV66373593; called by muse, mutect2, varscan2
- BTBD11 | c.2185C>G p.Q729E (on ENST00000280758 / NM_001018072.2; = p.Q266E on NM_001017523.2) | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.383); catalogued as COSV55017534, COSV55026018; called by muse, mutect2, varscan2
- C3orf56 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV67756305; called by muse, mutect2, varscan2
- C8orf37 | c.342T>G p.I114M | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV54412659; called by muse, mutect2, varscan2
- CACNA1B | c.4596A>T p.R1532S | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53129344; called by muse, mutect2, varscan2
- CACNA1F | c.4828G>T p.A1610S | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV59904944; called by muse, mutect2, varscan2
- CALCR | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs972789445, COSV64008823; called by muse, mutect2, varscan2
- CCDC81 | c.1692-1G>T p.X564_splice (on ENST00000445632 / NM_001156474.2; = p.X474_splice on NM_021827.4) | Splice Site (SNP) | VAF 10/53 reads (19%) | catalogued as COSV53579010; called by muse, mutect2, varscan2
- CDCA2 | c.2649G>T p.R883S | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV57946240; called by muse, mutect2, varscan2
- CDH19 | c.1021G>T p.V341F | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.215); catalogued as COSV50961022; called by muse, mutect2, varscan2
- CDH7 | c.92G>T p.R31M | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV59887556; called by muse, mutect2, varscan2
- CFAP47 | c.551C>A p.P184H | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV52885780; called by muse, mutect2, varscan2
- CNTNAP2 | c.1258G>T p.G420C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62192257; called by muse, mutect2, varscan2
- COCH | c.407C>A p.S136* (on ENST00000216361 / NM_001347720.1; = p.S71* on NM_004086.3) | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV53551315; called by muse, mutect2, varscan2
- COL19A1 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59575508; called by muse, mutect2, varscan2
- COL25A1 | c.1810G>T p.G604C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560702524, COSV67651458; called by muse, mutect2, varscan2
- COL8A2 | c.854C>A p.A285E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV57442099; called by muse, mutect2, varscan2
- CPT1C | c.1495G>T p.G499C | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54917922, COSV54919816; called by muse, mutect2, varscan2
- CRNKL1 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as rs532937612, COSV66106050; called by muse, mutect2, varscan2
- CTBP1 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs563992643, COSV99337927; called by muse, mutect2, varscan2
- CTHRC1 | c.304T>C p.W102R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.741); catalogued as rs1288074928, COSV57715700; called by muse, mutect2, varscan2
- CYP2C19 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 58/181 reads (32%) | catalogued as COSV64908015; called by muse, mutect2, varscan2
- DDIAS | c.2904T>G p.C968W | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV61272373; called by muse, mutect2, varscan2
- DMRT3 | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51905099; called by muse, mutect2, varscan2
- DNAH10 | c.9919G>T p.G3307C (on ENST00000409039; = p.G3246C on NM_207437.3) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV68995156; called by muse, mutect2, varscan2
- DOP1A | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52711516; called by muse, mutect2, varscan2
- DYRK3 | c.389A>G p.N130S | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65606493; called by muse, mutect2, varscan2
- DYSF | c.2473G>A p.G825S | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50446702; called by muse, mutect2, varscan2
- ENPP7 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV60386864; called by muse, mutect2, varscan2
- EPHA7 | c.1318C>A p.Q440K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV65184287; called by muse, mutect2, varscan2
- ESRP2 | c.2038G>C p.G680R (on ENST00000565858 / NM_001365264.1; = p.G670R on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52173931; called by muse, mutect2, varscan2
- FAIM2 | c.388G>T p.V130F | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV57739718; called by muse, mutect2, varscan2
- FAM171A1 | c.2092G>C p.G698R | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV65316764; called by muse, mutect2, varscan2
- FLG | c.2486C>A p.S829Y | Missense Mutation (SNP) | VAF 306/624 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.907); catalogued as COSV100911823; called by muse, varscan2
- FLRT2 | c.1585C>A p.H529N | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as COSV58143393; called by muse, mutect2, varscan2
- FNDC3B | c.1919G>T p.G640V | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61043692; called by muse, mutect2, varscan2
- FOXG1 | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57397184, COSV57397244; called by muse, mutect2, varscan2
- FUT10 | c.360A>C p.K120N | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV59452068, COSV59453841; called by muse, mutect2, varscan2
- GABRA6 | c.1091C>A p.P364H | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV50883193; called by muse, mutect2, varscan2
- GALNT17 | c.1582G>T p.V528L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV61166020; called by muse, mutect2, varscan2
- GEMIN8 | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.085); catalogued as COSV60550757; called by muse, mutect2, varscan2
- GTPBP10 | c.320-2A>T p.X107_splice | Splice Site (SNP) | VAF 22/69 reads (32%) | catalogued as COSV55987949; called by muse, mutect2, varscan2
- HOXC11 | c.435C>A p.S145R | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV54533373; called by muse, mutect2, varscan2
- HPSE2 | c.1667C>A p.P556Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65190982; called by muse, mutect2, varscan2
- IGFBP5 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760111422, COSV52082844; called by muse, mutect2, varscan2
- INPP4B | c.689-2A>G p.X230_splice | Splice Site (SNP) | VAF 4/23 reads (17%) | catalogued as COSV53728811; called by muse, mutect2
- INPPL1 | c.3467G>T p.R1156L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV53356328, COSV99996061; called by muse, mutect2, varscan2
- INSC | c.1487G>T p.R496L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771388775, COSV65410052, COSV65410480, COSV65411093; called by muse, mutect2, varscan2
- ITPRID2 | c.2057C>T p.S686F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57472723; called by muse, mutect2, varscan2
- JCAD | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.875); catalogued as COSV64759646; called by muse, mutect2, varscan2
- KALRN | c.4820G>A p.S1607N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.709); catalogued as COSV53767011; called by muse, mutect2, varscan2
- KDM6A | c.994A>T p.N332Y | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65041189; called by muse, mutect2, varscan2
- KDR | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV55767054; called by muse, mutect2, varscan2
- KEAP1 | c.839T>A p.F280Y | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV50293890; called by muse, mutect2, varscan2
- KIF11 | c.1196A>G p.Y399C | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751835131, COSV53268660; called by muse, mutect2, varscan2
- KLHL30 | c.141C>G p.H47Q | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59976079; called by muse, mutect2, varscan2
- KRT72 | c.974T>G p.L325R | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53374717; called by muse, mutect2, varscan2
- LAMB4 | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs576824303, COSV52721183; called by muse, mutect2, varscan2
- LARP4B | c.1640A>T p.E547V | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV60221829; called by muse, mutect2, varscan2
- LDB3 | c.1739G>C p.C580S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53942995; called by muse, mutect2, varscan2
- LHFPL6 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.402); catalogued as rs772534259, COSV65446618; called by muse, mutect2, varscan2
- LRP1B | c.10621G>A p.A3541T | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.596); catalogued as COSV67230218; called by muse, mutect2, varscan2
- LRP1B | c.2782C>A p.Q928K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV67208034, COSV67230224; called by muse, mutect2, varscan2
- LRRIQ3 | c.1002G>T p.Q334H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs984966858, COSV63044851; called by muse, mutect2, varscan2
- LRTM2 | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV54565314; called by muse, mutect2, varscan2
- MICAL2 | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV56321270; called by muse, mutect2, varscan2
- MKRN3 | c.1041G>T p.W347C | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58810208; called by muse, mutect2, varscan2
- MRGPRD | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58423336; called by muse, mutect2, varscan2
- MS4A6A | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV60619298; called by muse, mutect2, varscan2
- MTHFSD | c.550T>A p.C184S (on ENST00000360900 / NM_001159377.2; = p.C183S on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV59803656; called by muse, mutect2, varscan2
- MUC17 | c.3025G>T p.D1009Y | Missense Mutation (SNP) | VAF 108/920 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV60291171; called by muse, mutect2
- MUC17 | c.5321T>C p.I1774T | Missense Mutation (SNP) | VAF 166/575 reads (29%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs983318224, COSV60291176; called by muse, varscan2
- MYT1 | c.699G>T p.Q233H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV60507036; called by muse, mutect2, varscan2
- NEB | c.7114T>A p.C2372S | Missense Mutation (SNP) | VAF 83/311 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV51423704; called by muse, mutect2, varscan2
- NOX4 | c.1447T>A p.F483I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV54455033; called by muse, mutect2, varscan2
- NUP188 | c.2038A>T p.T680S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV65362828; called by muse, mutect2, varscan2
- OR13C5 | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1468783926, COSV101053137; called by muse, mutect2, varscan2
- OR1J4 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV61589914; called by muse, mutect2, varscan2
- OR2M5 | c.135G>C p.M45I | Missense Mutation (SNP) | VAF 106/359 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV63546411, COSV63546415; called by muse, mutect2, varscan2
- OR4C6 | c.623T>C p.I208T | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.461); catalogued as COSV58604404; called by muse, mutect2, varscan2
- OR52E2 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV58612773; called by muse, mutect2, varscan2
- OR6K6 | c.623A>T p.D208V (on ENST00000368144; = p.D184V on NM_001005184.1) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275893807, COSV63744301; called by muse, mutect2, varscan2
- PCDHA13 | c.2197G>T p.A733S | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV56485031, COSV56509935; called by muse, mutect2, varscan2
- PCDHA6 | c.2141C>A p.T714K | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as rs782042680, COSV65341953, COSV65344705; called by muse, mutect2, varscan2
- PCDHAC2 | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV53853207; called by muse, mutect2, varscan2
- PCDHB3 | c.1449C>A p.N483K | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554272471, COSV50577009, COSV50579745, COSV99165782; called by muse, mutect2, varscan2
- PCDHB9 | c.145G>C p.A49P | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV53379758; called by muse, mutect2, varscan2
- PCDHGA2 | c.1924C>A p.L642I | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV53945423; called by muse, mutect2, varscan2
- PCDHGB4 | c.1894G>T p.D632Y | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53963726, COSV99533628; called by muse, mutect2, varscan2
- PDCD7 | c.1287G>T p.Q429H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV52599988; called by muse, mutect2, varscan2
- PDGFRA | c.2806G>T p.E936* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV57269193; called by muse, mutect2, varscan2
- PHF3 | c.451A>G p.N151D | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV50321450; called by muse, mutect2, varscan2
- PNLIPRP3 | c.119C>A p.T40K | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV65048474, COSV65049414; called by muse, mutect2, varscan2
- POLE | c.396G>T p.E132D | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV57682141, COSV57693947; called by muse, mutect2, varscan2
- POLG2 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73376914; called by muse, mutect2, varscan2
- PRB4 | c.697G>T p.G233W | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.636); catalogued as COSV54397404, COSV54400933; called by muse, mutect2, varscan2
- PRDM9 | c.2478C>A p.H826Q | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57007476, COSV99689938; called by muse, mutect2, varscan2
- PRMT5 | c.1132G>C p.A378P | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53546723; called by muse, mutect2, varscan2
- PTPRB | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs753075904, COSV54243056; called by muse, mutect2, varscan2
- PTPRO | c.310G>C p.V104L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV55512292, COSV55523544; called by muse, mutect2, varscan2
- RANBP2 | c.7612A>T p.S2538C | Missense Mutation (SNP) | VAF 87/350 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV51702380; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1330C>T p.H444Y | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52863544; called by muse, mutect2, varscan2
- RBM6 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56483606; called by muse, mutect2, varscan2
- RCBTB2 | c.1117+1G>T p.X373_splice | Splice Site (SNP) | VAF 22/93 reads (24%) | catalogued as COSV60650413; called by muse, mutect2, varscan2
- RFX6 | c.155A>T p.Q52L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.034); catalogued as COSV60585933; called by muse, mutect2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RIN2 | c.2087A>T p.D696V (on ENST00000255006 / NM_001242581.1; = p.D647V on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1004336555, COSV54789159; called by muse, mutect2, varscan2
- RTCB | c.297G>T p.M99I | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV53279044; called by muse, mutect2, varscan2
- RUVBL1 | c.476T>G p.I159R | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV59476074; called by muse, mutect2
- RXFP2 | c.782G>A p.W261* | Nonsense Mutation (SNP) | VAF 32/145 reads (22%) | catalogued as COSV53636491; called by muse, mutect2, varscan2
- RYR2 | c.7105A>T p.S2369C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.198); catalogued as COSV63689848; called by muse, mutect2, varscan2
- RYR3 | c.2935C>A p.Q979K | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.725); catalogued as COSV66793527; called by muse, mutect2, varscan2
- SAMSN1 | c.1061T>A p.L354Q | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV53472583; called by muse, mutect2, varscan2
- SCN8A | c.4210C>A p.L1404M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61983408; called by muse, mutect2, varscan2
- SCYL2 | c.1930-2A>G p.X644_splice | Splice Site (SNP) | VAF 33/105 reads (31%) | catalogued as COSV62569152; called by muse, mutect2, varscan2
- SEMA6D | c.1520T>A p.I507N | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV60378529; called by muse, mutect2, varscan2
- SGCZ | c.409G>T p.G137* | Nonsense Mutation (SNP) | VAF 111/412 reads (27%) | catalogued as COSV66019533, COSV66027498; called by muse, mutect2, varscan2
- SHROOM1 | c.1402A>G p.S468G | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1296046905, COSV60581607; called by muse, mutect2, varscan2
- SI | c.1582C>G p.P528A | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52282692, COSV52303238; called by muse, mutect2, varscan2
- SIGLEC10 | c.106T>A p.C36S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100219243; called by muse, mutect2, varscan2
- SLC10A6 | c.224A>T p.Q75L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56721924; called by muse, mutect2, varscan2
- SLC24A2 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53866610; called by muse, mutect2, varscan2
- SLC38A8 | c.1102C>A p.L368I | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV55307258; called by muse, mutect2, varscan2
- SND1 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as rs1209887827, COSV61242200; called by muse, mutect2, varscan2
- SPAM1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs779755476, COSV56141188; called by muse, mutect2, varscan2
- SPATA5 | c.1969G>T p.G657C | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56777117; called by muse, mutect2, varscan2
- SPICE1 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV55621580; called by muse, mutect2, varscan2
- SPTA1 | c.5403G>C p.W1801C | Missense Mutation (SNP) | VAF 114/207 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63754553, COSV63758563; called by muse, mutect2, varscan2
- STK11 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58824706; called by muse, varscan2
- STK11 | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58824666, COSV58824737, COSV58824833; called by muse, varscan2
- SVEP1 | c.7905G>T p.E2635D | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52840058; called by muse, mutect2, varscan2
- SYNE2 | c.18824C>T p.S6275L | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1567659367, COSV100646565, COSV59953729; called by muse, mutect2, varscan2
- TAF1L | c.4468C>T p.Q1490* | Nonsense Mutation (SNP) | VAF 37/136 reads (27%) | catalogued as COSV54263115; called by muse, mutect2, varscan2
- TBKBP1 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs1255209704, COSV64653807; called by muse, mutect2, varscan2
- TBL1Y | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60733227; called by muse, mutect2, varscan2
- TEX15 | c.1321T>A p.Y441N (on ENST00000256246; = p.Y824N on NM_001350162.2) | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56347629; called by muse, mutect2, varscan2
- TGM2 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63931675; called by muse, mutect2, varscan2
- THEMIS | c.1151C>A p.S384Y | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV64071668; called by muse, mutect2, varscan2
- TLN1 | c.895G>T p.V299L | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as COSV100147719, COSV59208252; called by muse, mutect2, varscan2
- TMEM81 | c.352C>G p.R118G | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.666); catalogued as COSV52704943; called by muse, mutect2, varscan2
- TNFAIP6 | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs373889474, COSV54642596; called by muse, mutect2, varscan2
- TRMT1L | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 25/151 reads (17%) | catalogued as COSV62272511; called by muse, mutect2, varscan2
- TRPV3 | c.1388C>G p.P463R | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56792116; called by muse, mutect2, varscan2
- UGT1A5 | c.826A>T p.I276F | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV59390434; called by muse, mutect2, varscan2
- UNC13C | c.6503G>T p.W2168L | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV52881971; called by muse, mutect2, varscan2
- VAV3 | c.1831C>A p.L611M | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.192); catalogued as COSV58384123; called by muse, mutect2, varscan2
- ZIC1 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.495); catalogued as COSV51554290; called by muse, mutect2
- ZNF232 | c.1049A>G p.Q350R | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.055); catalogued as rs201796374, COSV51503727; called by muse, mutect2, varscan2
- ZNF320 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as rs1162618428, COSV67087503; called by muse, mutect2, varscan2
- ZNF551 | c.1975A>G p.I659V | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.009); catalogued as COSV56593366; called by muse, mutect2, varscan2
- ZNF695 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.861); catalogued as COSV60586254; called by muse, mutect2, varscan2
- ZNF98 | c.23T>A p.L8Q | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.044); catalogued as COSV100757545; called by muse, mutect2, varscan2
- ZNF98 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as COSV100757546; called by muse, mutect2, varscan2
- ZNFX1 | c.73G>T p.G25* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV65575963; called by muse, mutect2, varscan2
- AKAP13 | c.5381dup p.S1795Qfs*12 (on ENST00000394518 / NM_007200.5; = p.S1799Qfs*12 on NM_006738.6) | Frame Shift Ins (INS) | VAF 40/162 reads (25%) | called by mutect2, pindel, varscan2
- ASH1L | c.855del p.D286Ifs*12 | Frame Shift Del (DEL) | VAF 77/250 reads (31%) | called by pindel, varscan2*
- DTWD2 | c.647del p.P216Rfs*55 | Frame Shift Del (DEL) | VAF 13/93 reads (14%) | called by mutect2, pindel, varscan2
- PSG5 | c.125del p.P42Hfs*31 | Frame Shift Del (DEL) | VAF 65/257 reads (25%) | called by mutect2, pindel, varscan2
- RBM10 | c.48dup p.G17Wfs*4 | Frame Shift Ins (INS) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- RNF6 | c.1319del p.G440Afs*9 | Frame Shift Del (DEL) | VAF 27/125 reads (22%) | called by mutect2, pindel, varscan2
- SEC63 | c.2188del p.D730Ifs*4 | Frame Shift Del (DEL) | VAF 48/164 reads (29%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.3974C>A p.P1325Q | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TNS1 | c.3807_3832del p.P1270Sfs*11 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | called by mutect2, pindel
- VCX3B | c.111G>C p.K37N | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.197); called by mutect2, varscan2
- A2ML1 | c.1950C>A p.P650= | Silent (SNP) | VAF 81/251 reads (32%) | catalogued as COSV55292010; called by muse, mutect2, varscan2
- AKR1A1 | c.477G>T p.L159= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV61086939; called by muse, mutect2, varscan2
- ANAPC1 | c.5085G>T p.G1695= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs777518303, COSV100594926; called by muse, mutect2, varscan2
- AOX1 | c.3270G>T p.V1090= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as COSV53496283; called by muse, mutect2, varscan2
- ARAP3 | c.2103G>T p.R701= | Silent (SNP) | VAF 49/190 reads (26%) | catalogued as COSV53351244; called by muse, mutect2, varscan2
- BBS9 | c.993A>T p.V331= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV54171462; called by muse, mutect2, varscan2
- BTAF1 | c.2256G>T p.P752= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV56434983; called by muse, mutect2, varscan2
- CD1E | c.63C>A p.P21= | Silent (SNP) | VAF 108/216 reads (50%) | catalogued as COSV63771295; called by muse, mutect2, varscan2
- CLEC4D | c.531T>A p.S177= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV55229223; called by muse, mutect2, varscan2
- COLEC11 | c.120T>A p.P40= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV52594357; called by muse, mutect2, varscan2
- CRB2 | c.1197C>A p.G399= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV63503645; called by muse, mutect2, varscan2
- CRHBP | c.63G>A p.G21= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV57188793; called by muse, mutect2, varscan2
- CYP4A11 | c.705C>A p.A235= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV60223905; called by muse, mutect2, varscan2
- DNASE2B | c.297C>A p.A99= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV101042929; called by muse, mutect2, varscan2
- EFCAB5 | c.3552G>A p.T1184= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1268424060, COSV57931338; called by muse, mutect2, varscan2
- F5 | c.1572A>T p.L524= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV63124925; called by muse, varscan2
- FAR1 | c.327C>T p.F109= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV61385052; called by muse, mutect2
- FGD6 | c.1833G>T p.V611= | Silent (SNP) | VAF 71/233 reads (30%) | catalogued as COSV59693812; called by muse, mutect2, varscan2
- FLG | c.2487C>A p.S829= | Silent (SNP) | VAF 306/627 reads (49%) | catalogued as COSV100911822, COSV64244038; called by muse, varscan2
- GLRX3 | c.663A>G p.A221= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV58692974; called by muse, mutect2, varscan2
- GPR179 | c.3511C>A p.R1171= (on ENST00000621958; = p.R1170= on NM_001004334.4) | Silent (SNP) | VAF 59/233 reads (25%) | called by muse, mutect2, varscan2
- GRK5 | c.786C>A p.V262= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV64866575; called by muse, mutect2, varscan2
- IGSF9B | c.3684C>A p.L1228= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV58068658; called by muse, mutect2, varscan2
- INPP5D | c.2118C>A p.A706= (on ENST00000445964 / NM_001017915.3; = p.A705= on NM_005541.5) | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV64037685; called by muse, mutect2, varscan2
- INTS1 | c.1092G>T p.R364= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV67177881; called by muse, mutect2, varscan2
- IPO5 | c.444G>A p.R148= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV55155249; called by muse, mutect2, varscan2
- ITGB3 | c.526C>A p.R176= | Silent (SNP) | VAF 49/157 reads (31%) | catalogued as COSV71383462, COSV71384207; called by muse, mutect2, varscan2
- ITPK1 | c.1038G>T p.A346= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99968731; called by muse, mutect2, varscan2
- JMJD1C | c.4356C>T p.T1452= | Silent (SNP) | VAF 47/159 reads (30%) | catalogued as COSV59515633; called by muse, mutect2, varscan2
- LMNA | c.36C>T p.S12= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV61543126; called by muse, mutect2
- LRRC40 | c.1806T>G p.T602= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs1200827161, COSV63942478; called by muse, mutect2, varscan2
- LRRC4C | c.378C>A p.L126= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV53427759, COSV53440131; called by muse, mutect2, varscan2
- MAP1LC3C | c.360C>A p.A120= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV61803783; called by muse, mutect2, varscan2
- MNDA | c.795C>A p.V265= | Silent (SNP) | VAF 45/88 reads (51%) | catalogued as COSV100933341, COSV63741024; called by muse, varscan2
- MRGPRX2 | c.561T>A p.T187= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV61674297; called by muse, mutect2, varscan2
- NCKAP1 | c.2091A>G p.V697= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as rs1243188941, COSV62941536; called by muse, mutect2, varscan2
- NLRP2 | c.1989G>A p.P663= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs748791961, COSV54756172, COSV54760925; called by muse, mutect2, varscan2
- NLRP5 | c.1668C>A p.L556= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV66765225, COSV66765945; called by muse, mutect2, varscan2
- NOD2 | c.921G>T p.T307= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV56051674; called by muse, mutect2, varscan2
- OR10J1 | c.648T>C p.S216= | Silent (SNP) | VAF 38/181 reads (21%) | catalogued as COSV71128959; called by muse, mutect2, varscan2
- OR13C5 | c.222C>A p.T74= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV101053135; called by muse, mutect2, varscan2
- PCDH11X | c.720T>C p.T240= | Silent (SNP) | VAF 61/115 reads (53%) | catalogued as COSV53473003; called by muse, mutect2, varscan2
- PDGFRA | c.2397C>A p.T799= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV57269184; called by muse, mutect2, varscan2
- PHETA1 | c.189G>T p.L63= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV64059179; called by muse, mutect2, varscan2
- PIM1 | c.42C>T p.A14= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs778415475, COSV65165809; called by muse, mutect2, varscan2
- POLE | c.6042G>T p.G2014= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV57682129; called by muse, mutect2, varscan2
- PRUNE2 | c.7998C>A p.L2666= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV65040204, COSV65042388; called by muse, mutect2, varscan2
- PSG6 | c.654A>T p.I218= | Silent (SNP) | VAF 159/510 reads (31%) | catalogued as COSV51833891; called by muse, mutect2, varscan2
- RANGAP1 | c.160C>T p.L54= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV62363705; called by muse, mutect2
- RGL1 | c.1683G>C p.S561= (on ENST00000360851 / NM_001297672.2; = p.S596= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs199702533, COSV58987093; called by muse, mutect2, varscan2
- RHBDD2 | c.537C>T p.P179= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV50087228; called by muse, mutect2, varscan2
- SCN5A | c.2397C>A p.S799= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV61127124; called by muse, mutect2
- SCN8A | c.3639C>A p.G1213= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV61983400; called by muse, mutect2, varscan2
- SIGLEC10 | c.105G>A p.L35= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV100219247; called by muse, mutect2, varscan2
- SPECC1L | c.1482T>A p.R494= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as COSV58659029; called by muse, mutect2, varscan2
- SPINK4 | c.234C>A p.I78= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV65688070; called by muse, mutect2, varscan2
- STEAP4 | c.654T>C p.C218= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs753995258, COSV57329853; called by muse, mutect2, varscan2
- UNC13C | c.3141C>T p.V1047= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV52881945; called by muse, mutect2, varscan2
- URB2 | c.2025A>G p.E675= | Silent (SNP) | VAF 42/191 reads (22%) | catalogued as COSV50995558; called by muse, mutect2, varscan2
- USH2A | c.10374G>T p.T3458= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV56381276; called by muse, mutect2, varscan2
- USP6 | c.2892C>T p.S964= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV51484624; called by muse, mutect2, varscan2
- VCAN | c.7023A>T p.A2341= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV54107091; called by muse, mutect2, varscan2
- VN1R1 | c.183G>T p.L61= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV58091172; called by muse, mutect2, varscan2
- ZNF217 | c.1158C>A p.T386= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV56597961; called by muse, mutect2, varscan2
- ZNF578 | c.825A>T p.A275= | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as COSV69736675; called by muse, mutect2, varscan2
- AC245047.1 | n.72A>C | RNA (SNP) | VAF 55/98 reads (56%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847806 G>T | 5'Flank (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2, varscan2
- CHRM2 | c.-47+33864G>T | Intron (SNP) | VAF 21/81 reads (26%) | catalogued as COSV57774292; called by muse, mutect2, varscan2
- MRTFB | c.1079+298C>T | Intron (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100371559; called by muse, mutect2
- NDUFV3 | c.170-5284G>T | Intron (SNP) | VAF 40/114 reads (35%) | catalogued as rs756757084, COSV100447072; called by muse, mutect2, varscan2
- TLE3 | c.235-3299G>T | Intron (SNP) | VAF 6/22 reads (27%) | catalogued as COSV58170401; called by muse, mutect2
